Surgical pathology report (de-identified scan), TCGA case TCGA-S9-A6UA, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Dept of Neurosurgery at University of Heidelberg, specimen TCGA-S9-A6UA-01A (Primary Tumor).

Neuropathology

Commentary:

Histology and morphology correspond to anaplastic astrocytoma WHO grade III.

Diagnosis:

Anaplastic astrocytoma WHO grade III

CQCF ICD-0-3
Astrocytoma, grade III
path 9401/3
Astrocytoma, anaplastic
9401/3
Site: Brain, supratentorial H&S
QW 7/25/13 C71.0

Untranslated original report
is housed at the BCR.

ICDPA Discrepancy		✓

Source: NCI Genomic Data Commons file dfc7f267-8a14-4afc-92dc-686a638c1474 (TCGA-S9-A6UA.7F0ED679-C54A-4B51-ACD8-CF1E2EB2BCFA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).